Gene-level copy-number profile of specimen HCM-SANG-0309-C15-85A from HCMI case HCM-SANG-0309-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0309-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e875ec4d-e659-4c60-bfb4-d7cd029ef735.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0309-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,755 have no estimate.
https://portal.gdc.cancer.gov/files/acda5a31-f508-4523-afab-8b4957540383

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 413; copy number 2: 19,552; copy number 3: 11,074; copy number 4: 14,556; copy number 5: 7,880; copy number 6: 2,738; copy number 7: 1,289; copy number 8: 745; copy number 9: 74; copy number 10: 27; copy number 11: 214; copy number 12: 19; copy number 13: 28; copy number 14: 30; copy number 15: 52; copy number 16: 9; copy number 17: 4; copy number 18: 3; copy number 19: 1; copy number 20: 4; copy number 21: 104; copy number 23: 2; copy number 26: 2; copy number 28: 4; copy number 36: 20; copy number 37: 4; copy number 40: 15; copy number 45: 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,507,452–19,895,973, 4 genes: SLC24A2, C11orf98P1, AL158077.2, AL158077.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13,269 genes in 134 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–13,617,957, 467 genes, copy number 5–9 (broad region; genes not listed).
- chr1:143,419,625–198,540,945, 1,415 genes, copy number 5–9 (broad region; genes not listed).
- chr2:38,814–58,296,817, 910 genes, copy number 5–9 (broad region; genes not listed).
- chr2:86,720,291–91,963,610, 163 genes, copy number 5–16 (within-gene range 2–16) (broad region; genes not listed).
- chr2:96,593,170–101,521,976, 113 genes, copy number 9–28 (broad region; genes not listed).
- chr2:102,714,630–106,078,155, 51 genes, copy number 5–6 (within-gene range 4–6): MFSD9, TMEM182, LINC01796, LINC01935, AC108051.1, AC073987.1, AC010881.1, CRLF3P1, AC018880.1, CAPZBP1, AC013727.1, AC013727.2, LINC01965, AC013727.3, AC096554.1, AHCYP3, AC068535.1, LINC01831, LINC01102, LINC01103, AC013402.2, AC013402.3, AC068057.3, AC013402.1, RPL23AP27, AC068057.1, AC068057.2, SNORA72, LINC01114, HMGB3P11, PANTR1, AC018730.1, POU3F3, LINC01159, AC010884.1, MRPS9-AS2, MRPS9, MRPS9-AS1, LINC01918, GPR45, AC012360.2, TGFBRAP1, AC012360.1, AC012360.3, C2orf49, FHL2, AC108058.1, NCK2, AC010978.1, AC009505.1, ECRG4.
- chr2:109,542,799–111,120,610, 46 genes, copy number 5 (within-gene range 4–5): SEPTIN10, RPL37P12, AC011753.2, SOWAHC, AC011753.1, BMS1P19, SRSF3P6, RPL22P11, RGPD5, LIMS3, AC013271.1, AC013268.1, AC013268.5, GPAA1P1, ZBTB45P1, LINC01123, AC013268.3, AC013268.2, MIR4267, MALL, MIR4436B1, NPHP1, ACTR1AP1, MTLN, AC140479.3, AC140479.4, MALLP1, MIR4436B2, AC140479.1, AC140479.2, LINC01106, ZBTB45P2, GPAA1P2, AC112229.4, AC112229.1, AC112229.3, LIMS4, AC112229.2, AC108938.1, RGPD6, AC226101.1, RPL22P12, BUB1, AC114776.1, ACOXL, RPL5P9.
- chr5:50,396,192–56,606,232, 112 genes, copy number 5 (broad region; genes not listed).
- chr7:7,906,519–24,694,193, 198 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:29,514,224–43,113,931, 229 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:46,549,089–117,540,262, 1,020 genes, copy number 5 (broad region; genes not listed).
- chr8:118,620,498–145,066,685, 470 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr9:26,840,685–33,514,773, 87 genes, copy number 5–8 (broad region; genes not listed).
- chr9:34,889,066–37,592,604, 106 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr9:38,147,428–40,883,763, 72 genes, copy number 5–7 (broad region; genes not listed).
- chr9:42,183,659–72,365,235, 252 genes, copy number 5–8 (broad region; genes not listed).
- chr10:14,061–20,552,046, 323 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr10:21,321,961–38,783,108, 312 genes, copy number 5–6 (within-gene range 5–7) (broad region; genes not listed).
- chr11:68,052,859–85,935,663, 409 genes, copy number 5–11 (within-gene range 4–11) (broad region; genes not listed).
- chr12:50,057,548–52,652,211, 105 genes, copy number 5 (broad region; genes not listed).
- chr12:52,821,408–53,898,976, 53 genes, copy number 5 (within-gene range 4–5): KRT79, AC107016.1, KRT78, RPL7P41, KRT8, KRT18, EIF4B, AC068888.2, AC068888.1, TNS2, MIR6757, SPRYD3, IGFBP6, SOAT2, VTI1BP3, RNU6-333P, HIGD1AP1, EIF4A1P4, CSAD, AC073573.1, ZNF740, ITGB7, RARG, MFSD5, ESPL1, PFDN5, AC073611.1, MYG1-AS1, MYG1, AAAS, SP7, SP1, AMHR2, PRR13, AC023509.1, PCBP2, PCBP2-OT1, AC023509.4, MAP3K12, AC023509.3, TARBP2, ATF7-NPFF, NPFF, ATF7, AC023509.2, AC023509.6, AC023509.5, ATP5MC2, AC073594.1, CALCOCO1, AC076968.2, CISTR, AC076968.1.
- chr12:53,935,328–56,636,816, 172 genes, copy number 5–7 (broad region; genes not listed).
- chr12:57,591,174–62,935,150, 83 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:62,935,701–121,080,124, 1,045 genes, copy number 5–8 (broad region; genes not listed).
- chr13:18,467,172–24,597,676, 160 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr14:19,024,090–21,476,960, 154 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr14:21,521,080–22,982,258, 171 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr14:23,095,505–51,397,135, 473 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr14:51,454,512–54,793,315, 61 genes, copy number 5 (broad region; genes not listed).
- chr15:59,525,422–80,597,933, 562 genes, copy number 5–6 (broad region; genes not listed).
- chr16:13,728,654–18,379,331, 127 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr16:31,952,160–46,831,180, 208 genes, copy number 5 (broad region; genes not listed).
- chr16:69,950,705–71,309,963, 45 genes, copy number 5–6: CLEC18A, AC026468.1, PDXDC2P-NPIPB14P, NPIPB14P, PDXDC2P, MIR1972-2, AC009022.1, PDPR, AC009060.1, CLEC18C, AC009060.2, SMG1P7, EXOSC6, AARS1, RN7SL279P, DDX19B, AC012184.2, AC012184.3, DDX19A, AC012184.4, ST3GAL2, AC012184.1, RPS27P26, RNU6-23P, FCSK, COG4, SF3B3, SNORD111B, SNORD111, IL34, MTSS2, AC020763.4, VAC14, AC020763.3, AC020763.1, VAC14-AS1, AC020763.5, AC020763.2, AC027281.1, HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1, CMTR2, AC106736.1.
- chr16:72,728,616–75,861,157, 87 genes, copy number 5 (within-gene range 5–6) (broad region; genes not listed).
- chr17:39,156,894–42,874,369, 237 genes, copy number 5–45 (broad region; genes not listed).
- chr18:45,034–15,330,282, 367 genes, copy number 8 (broad region; genes not listed).
- chr18:22,586,465–27,595,164, 92 genes, copy number 5–21 (broad region; genes not listed).
- chr19:27,638,483–40,426,702, 473 genes, copy number 5–21 (broad region; genes not listed).
- chr20:87,250–36,051,018, 730 genes, copy number 5–7 (broad region; genes not listed).
- chr20:62,477,870–64,327,972, 114 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 413. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
